Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB36, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB36-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:

with recurrent chest wall liposarcoma.

Specimens Submitted:

1: SP: Right chest wall

DIAGNOSIS:

- 1) RIGHT CHEST WALL; EXCISION:
- DEDIFFERENTIATED LIPOSARCOMA ARISING IN A WELL-DIFFERENTIATED COMPONENT.
- THE DEDIFFERENTIATED COMPONENT PREDOMINATES AND IS COMPOSED OF A PLEOMORPHIC HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA-LIKE MORPHOLOGY.
- TUMOR INVOLVES THE CHEST WALL SOFT TISSUE AND FOCALLY ERODING INTO BOTH UPPER AND LOWER RIBS.
- THE TUMOR MEASURES 8.1 X 4.5 X 4.3 CM.
- RIB MARGINS ARE FREE OF TUMOR.
- THE LOW GRADE WELL-DIFFERENTIATED SCLEROSING COMPONENT EXTENDS TO THE ANTERIOR SOFT TISSUE MARGIN.

NOTE: PERFORMED IMMUNOSTAINS ARE STRONGLY POSITIVE FOR CDK4 AND MDM2, SUPPORTING THE ABOVE DIAGNOSIS. WE HAVE REVIEWED THE PRIOR MATERIAL FROM THE RESECTION IN RETROSPECT, THE MORPHOLOGICAL FEATURES ARE MOST CONSISTENT WITH A WELL-DIFFERENTIATED LIPOSARCOMA, SCLEROSING TYPE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1).The specimen is received fresh labeled, *right chest wall, single stitch

** Continued on next page **

ICD.O 3

Liposarcoma, dedifferentiated
88551/3

Site - Chest wall NOS
C49.3

4/3/10/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
marks superior, double stitch marks posterior", and consists of a chest wall excision consisting of two ribs, tumor in soft tissue, measuring overall 11.5 x 6.6 x 5.5 cm. The pleural surface is smooth and glistening and distended by tumor and tumor abuts the pleural surface and extends between the two ribs into the anterior soft tissue. The anterior soft tissue is inked black, the posterior rib margins are inked yellow and the anterior rib margins are inked red. The superficial rib is designated rib number one, the inferior rib is designated rib number two. The tumor measures 8.1 x 4.5 x 4.3 cm and is firm, with a white to tan cut surface. Grossly the tumor does not appear to involve the ribs. The tumor measures 0.3 cm to the anterior soft tissue margin. Tissue is submitted for TPS and photographs are taken.

Summary of sections:

PM1 -- posterior margin rib, number one
AM1-- anterior margin rib number one
PM2 -- posterior margin rib number two
AM2 -- anterior margin rib number two
TP -- tumor to pleura
TST -- tumor to soft tissue
T - tumor
TR1 - tumor to rib number one
TR2 - tumor to rib number two

Summary of Sections:

Part 1: SP: Right chest wall

Block	Sect. Site	PCs
1	AM1	1
1	AM2	1
1	PM1	1
1	PM2	1
3	T	3
2	TP	2
1	TR1	1
1	TR2	1
3	TST	3

** End of Report **

Source: NCI Genomic Data Commons file 39c98403-ebb3-4eba-9ac7-c2f898bf8d1c (TCGA-DX-AB36.B59B3034-8B4B-4E52-8F68-E8CBE90F06F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).